Surgical pathology report (de-identified scan), TCGA case TCGA-QQ-A5VB, project TCGA-SARC (Sarcoma), tissue source site Roswell Park, specimen TCGA-QQ-A5VB-01A (Primary Tumor).

[page 1 of 3]
FILE COPY

Name: [REDACTED]
Address: [REDACTED]

Chart No.: [REDACTED]
Age: [REDACTED]
Sex: [REDACTED]

Service: [REDACTED]

Pathology No.: [REDACTED]
Date: [REDACTED]

CLINICAL HISTORY

year old white female noted lump in groin with increase in tenderness and pain. CT scan showed solid mass. Biopsied, reported as high grade leiomyosarcoma; referred to [REDACTED] for resection
Yes No Unknown

Does the patient have:

Hepatitis		X
TB		X
Previous biopsy	X	
Previous chemotherapy		X
Previous radiation		X

PRE-OPERATIVE DIAGNOSIS AND DIFFERENTIAL:

Left groin sarcoma

POST-OPERATIVE DIAGNOSIS: NG

SPECIFIC QUESTIONS TO BE ANSWERED BY CONSULTATION (if any): NG

OPERATION: NG

SPECIMENS:

#1 left iliac node
#2: left groin sarcoma
#3 deep margin

FROZEN SECTION DIAGNOSIS BY

FS2: sarcoma at lateral margin

GROSS DESCRIPTION:

#1 Received is a portion of fibroadipose tissue which appears to contain at least one lymph node and measures 4.5x0.6x0.3cm. The specimen is bisected and cut section shows scattered lymphoid parenchyma infiltrated by adipose tissue. The specimen is submitted in toto in one cassette.
#2 Received is an ellipse of skin with attached tumor, subcutaneous tissue, muscle and blood vessels measuring 13.2x9.0x6.4cm. in overall dimension. The ellipse of skin measures 8.5x2.5x0.2cm. and is

ICD-0-3 8592/3
Site: Left Groin
Leiomysarcoma NOS
Soft tissues of groin 849.5
Connective, subcutaneous and other soft tissues of extremities 849.9
4/12/13 and

[page 2 of 3]
Name: [REDACTED]

Chart No: [REDACTED] Control No: [REDACTED]

tan/pink with focal areas of puckering in an old healed scar measuring 3.5cm. in length. There is a firm, circumscribed pseudoencapsulated tumor situated 3.3cm. from the skin measuring 5.6x4.8x4.6cm. and appears to involve the lateral deep margin (with the pseudocapsule). Cut section shows a tan lobulated bulging surface with no evidence of hemorrhage or necrosis. There are multiple blood vessels coursing through the tumor, the largest measuring 6.0x0.3cm. The free margin of the vessel is occluded by organizing thrombus and cut section through the occlusion reveals occlusion by tumor thrombus. The tumor is 1.5cm. from the proximal margin, 4.5cm. from the distal margin and appears approximately 2cm. from the medial margin. The lateral deep margin is inked black. The deep margin is inked blue. Representative sections are taken as submitted as follows:

PS2A-lateral deep margin

PS2B-vascular margin

2VM-vascular margin

2DM-deep margin

2LS-lateral margin

2T1 and 2T2-representative sections of tumor.

#3 Received are six small nodules of fibroadipose/muscular tissue ranging from 1.4x0.9x0.5cm. to 0.5x0.4x0.3cm. This specimen is unoriented. The largest portions are bisected and specimens are submitted in toto in 3A to 3C.

Total blocks: 10

DIAGNOSTIC

- 1) LYMPH NODE, LEFT ILLIAC, EXCISION: THREE LYMPH NODES (0/3),
NEGATIVE FOR TUMOR
- 2) TUMOR, LEFT GROIN, EXCISION: HIGH GRADE LEIOMYOSARCOMA INVADING
NEUROVASCULAR BUNDLES WITH TUMOR THROMBUS FORMATION (SEE NOTE).
THE LATERAL DEEP MARGIN IS POSITIVE (SEE NOTE)
- 3) DEEP MARGIN, EXCISION: FRAGMENTS OF SKELETAL MUSCLE, NO TUMOR
SEEN

[page 3 of 3]
Name: _____

Chart No: _____

Control No: _____

HIST: #2 Tumor shows 7-8 mitotic figures per 10 HPF with areas of coagulative tumor necrosis and hyalinization. The lateral deep margin is positive; however, the attached margin labeled #3 is free of tumor.

Source: NCI Genomic Data Commons file 5ecb4165-4cd8-4b91-9449-2d494d9cfd18 (TCGA-QQ-A5VB.C437CF62-4A74-4A90-A168-84C92DE62AB2.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).